Surgical pathology report (de-identified scan), TCGA case TCGA-51-4080, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-51-4080-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

FSA: Soft tissue, trachea, biopsy

- Squamous cell carcinoma in situ.
- Scant stroma, no invasive carcinoma identified.

FSB: Lymph nodes, R4, biopsy

- No metastatic carcinoma identified (0/5 lymph node fragments).

FSC: Lymph nodes, station 7, biopsy

- No metastatic carcinoma identified (0/7 lymph node fragments).

FSD: Lymph nodes, area 7, biopsy

- No metastatic carcinoma identified (0/26 lymph node fragments).

FSE: Lymph nodes, area 4, biopsy

- No metastatic carcinoma identified (0/24 lymph node fragments).

FSF, F: Lung, right, pneumonectomy

Tumor histologic type (WHO): squamous cell carcinoma, usual and basaloid variant subtypes

Tumor histologic grade (WHO): moderate to poorly differentiated

Tumor size (greatest dimension): 5.0 cm

[page 2 of 5]
Other structures involved: none

Pleural involvement: not identified

In situ carcinoma: present

Extent of invasion:
vascular not definitely identified. perineural not
identified satellite nodules present (2, same lobe, 1.6cm
and 1.7cm diameters)

Surgical margins: not involved

Lymph nodes: metastatic squamous carcinoma (3/15) (F7, F9,
F10)

Extracapsular extension in nodes: not identified

Findings in nontumorous lung: anthracosis

AJCC Staging: pT4 pN1 pMx

This staging information is based on this pathologic
specimen and may be incomplete. A comprehensive review of
all available information is recommended to determine final
staging.

G: Lymph nodes, level 9, biopsy
- No metastatic carcinoma identified (0/3).

H: Lymph nodes, level 10, biopsy
- No metastatic carcinoma identified (0/2).

Intraoperative Consult Diagnosis:

Frozen section was requested by [REDACTED]

FSA1: Soft tissue, trachea, biopsy
- Squamous cell carcinoma in situ, no invasive carcinoma
identified, but scant
stroma available for evaluation
Dr. has reviewed slides (levels 1 and 2) and concurs.

FSB1: Lymph node, R4, biopsy
- Lymph node fragments with no carcinoma identified

FSC1: Lymph node, station 7, biopsy

[page 3 of 5]
- Lymph node fragments with no carcinoma identified

FSD1 and FSD2: Lymph node, area 7, biopsy

- Enlarged lymph node; representative sections negative for carcinoma

FSE1 and FSE2: Lymph node, area 4, biopsy

- Representative sections of lymph nodes, negative for carcinoma

FSF1: Lung, right, "tracheal margin", thoracotomy

- Tracheal margin with no carcinoma identified (invasive or in situ)

Frozen Section Pathologist:

Clinical History:

with right upper lobe carcinoma (SCC). CIS: Rads: Pre-op PET shows a R suprahilar mass with regional signal c/w nodes, without ENT or abdominal signal to suggest metastases to the lung.

Gross Description:

Specimen A is received fresh for frozen section and is a 0.4 x 0.2 x 0.1 cm aggregate of red/tan soft tissue fragments that are submitted in FSA1, NTR.

Specimen B is received fresh for frozen section and is a 0.6 x 0.5 x 0.4 cm aggregate of four black/tan lymph node candidates that are submitted in FSB1, NTR.

Specimen C is received fresh for frozen section and subsequently placed in formalin and is a 0.9 x 0.5 x 0.3 cm aggregate of five black/tan lymph node candidates that are submitted in FSC1, NTR. Specimen D is received fresh for frozen section and subsequently placed in formalin and is a 7.1 gram 5 x 3.5 x 1.0 cm aggregate of red/tan lobulated tissue fragments containing numerous lymph node candidates. Representative sections are submitted as frozen section FSD1-FSD2 and the frozen section remnants are submitted in D1-D6.

Specimen E is received fresh for frozen section and is a 6.7 gram, 4 x 2.6 x 1.0 cm aggregate of lymph node candidates. A representative section is frozen

[page 4 of 5]
as FSE1-FSE2. Frozen section remnant is submitted in block FSE1 and FSE2. The remainder of the specimen is submitted in block E1-E4.

Specimen F is received fresh for frozen section and subsequently placed in formalin and labeled "right lung, trachea, carina, stitch marks tracheal margin".

Specimen fixation: Formalin

Type of specimen/parts of lung received: Right pneumonectomy

Size of specimen: 18 x 14.5 x 8.1 cm

Weight of specimen: 600 grams

Other attached structures: 6.0 cm long x 2.0 cm in diameter tracheal

Orientation: Inking: Pleura over main mass/blue, pleura over satellite lesion #1/black, pleura over satellite lesion #2/green.

Tumor location: Central, located in the fissure between the upper and lobe at the upper bronchus.

Tumor size: 5 x 4.5 x 4.3 cm

Relationship of tumor to bronchus: The tumor encases and invades the upper lobe bronchus. The tumor grossly invades across the linea fissure between the upper and lower lobe into and adjacent fissure lymph node. The tumor grossly abuts and distorts the wall of the hilar vessels.

Distance of tumor to tracheal margin: 2.4 cm

Relationship/distance of tumor to pleura: Grossly abuts

Distance of tumor to other surgical margins: The tumor grossly abuts the hilar vasculature.

Presence/absence of satellite tumor nodules: Present. Lesion 1 (1.6 x 1.0 x 0.8 cm) located 1.6 cm superior to the main mass. This lesion grossly abuts the pleura (inked blue) and is located 0.8 cm from lesion 2. Lesion 2 (1.7 x 1.0 x 0.6 cm) located 3.0 cm superior to the main

[page 5 of 5]
mass and 0.8 cm from lesion 1. This lesion grossly abuts the green inked pleura.

Involvement of attached structures by tumor: The tumor grossly abuts the attached trachea.

Description of nontumorous lung: The upper lobe is red and spongy with abundant mucous plugs. The lower lobe is tan/pink, spongy and grossly unremarkable. No mass lesions are identified. The middle lobe is tan/pink spongy and no mass lesions are identified.

Digital photograph taken: No

Tissue submitted for special investigation: Yes. Tumor and normal to tissue procurement.

Block Summary:

Inking: Pleura overlying main mass/blue, pleura over lesion 1/black, pleura

over lesion 2/green

F1-F2 - Vascular margins

F3 - Tracheal margin, superseded by frozen section

F4-F5 - Hilar lymph nodes

F6 - Tumor invading upper lobe bronchus

F7 - Tumor abutting hilar vessels

F8 - Tumor with adjacent hilar lymph node

F9-F10 - Tumor with respect to upper lobe and lower lobe linear fissure and fissure lymph node

F11 - Tumor with overlying blue inked pleura

F12 - Tumor with adjacent normal

F13 - Tumor with respect to lesion #1 (black)

F14 - Parenchyma between lesion #1 and #2

F15 - Lesion #2 (green)

F16 - Representative sections of lower lobe parenchyma

F17 - Representative sections of middle lobe parenchyma

Specimen G is received in a formalin-filled container labeled "level 9" and is a 2.0 x 0.8 x 0.4 cm fragment of tan/brown soft tissue submitted entirely in block G1.

Specimen H is received in a formalin-filled container labeled "level 10" and is a 1.5 x 0.7 x 0.4 cm fragment of tan/brown soft tissue submitted entirely in block H1.

Source: NCI Genomic Data Commons file 2f638f4b-7ef5-4278-8dc2-d6be124d7fef (TCGA-51-4080.4142077F-F67B-46F9-9302-18BA26E15E27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).